Gene-level copy-number profile of tumor specimen TCGA-BP-4763-01A from TCGA case TCGA-BP-4763, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 79.8 years (29,150 days).
Specimen TCGA-BP-4763-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.6d838fe5-3169-474e-b62a-4a84a194ece9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BP-4763-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2f35eedc-3938-4dec-86b8-77aa279d398b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 8,899; copy number 2: 43,131; copy number 3: 7,746.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-BP-4763-01): tumor purity 0.41, ploidy 2.01, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:15,290,718–16,582,707, 42 genes: AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7, POTEH, POTEH-AS1, RNU6-816P, AP000529.1, PSLNR, GRAMD4P2, DUXAP8, AP000526.1, BMS1P22, AP000525.1, DUXAP8, NBEAP3, TOMM40P2, AP000522.1, AC145543.1, U6, ABCD1P4, AC137499.1, PABPC1P9, SLC9B1P4, ACTR3BP6, CHEK2P4, AP000547.2, AP000547.1, KCNMB3P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,811. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
